Surgical pathology report (de-identified scan), TCGA case TCGA-32-1982, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1982-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Right parietal tumor
2. Right parietal tumor

GBM [REDACTED]
CONTROL [REDACTED]

CLINICAL DIAGNOSIS:

Brain tumor

TCGA-32-1982

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name are two tan-red soft tissues measuring 1.2 x 0.9 x 0.8 cm and 0.8 x 0.7 x 0.4 cm. The larger portion is bivalved. Representative sections are submitted as follows:
[REDACTED] Smaller portion of soft tissue and half of the larger portion

FROZEN SECTION DIAGNOSIS:

GLIAL NEOPLASM INTERMEDIATE TO HIGH GRADE. [REDACTED]

Tissue submitted for frozen is subsequently submitted for permanent. The remainder of the tissue is submitted in cassettes 1B.

2. Received in formalin labeled with the patient's name and "parietal tumor" is a 4.0 x 2.5 x 2.4 cm tan-red soft tissue. The specimen surface is shaggy. Also present in the container are multiple small portions of tan-red shaggy soft tissue aggregating to 2.4 x 1.5 x 0.8 cm. The largest portion is serially sectioned to reveal a tan-yellow homogenous cut surface. Entirely submitted as follows:

- A-F) Serial sections of largest portion of soft tissue
- G) Unattached soft tissues also present in the container

MICROSCOPIC DESCRIPTION:

- 1, 2. Sections demonstrate a markedly hypercellular glial neoplasm, the cells of which resemble moderately atypical fibrillary astrocytes. Numerous scattered mitotic figures are seen. Microvascular proliferation is focally prominent. Foci of confluent tumor necrosis are seen.

DIAGNOSIS:

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Approximately 10-25% of cells are immunoreactive for MGMT in a patchy distribution. These include many definite tumor cells.

ADDENDUM DIAGNOSIS:

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA
- TUMOR CELLS POSITIVE FOR MGMT EXPRESSION.

Source: NCI Genomic Data Commons file daaf1d56-180c-456c-ba11-9b60995265b1 (TCGA-32-1982.CD26781A-EC25-4240-BEAC-F45CC7A2B7A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).